Somatic mutation profile of tumor specimen MP2PRT-PAPTRI-TMP1-A (aliquot MP2PRT-PAPTRI-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPTRI, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.9 years (701 days).
Specimen MP2PRT-PAPTRI-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab141d0b-4b89-458d-876d-155d79da3534.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPTRI-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPTRI-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d942560-64c8-4b5f-b6c1-c2382f413d08

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.713C>G p.S238* | Nonsense Mutation (SNP) | VAF 13/314 reads (4%) | catalogued as COSV50466229, COSV50478927; called by muse, mutect2
- DNAH5 | c.4487G>T p.W1496L | Missense Mutation (SNP) | VAF 131/323 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99448756; called by muse, mutect2, varscan2
- H3C4 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV61911531, COSV61912198, COSV61912262; called by muse, mutect2, varscan2
- NIPAL4 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1442509035, COSV61730254; called by muse, mutect2
- NPAP1 | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 32/396 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as rs780506627, COSV61503994; called by muse, mutect2
- PCARE | c.3136C>T p.R1046W | Missense Mutation (SNP) | VAF 169/362 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.292); catalogued as rs756012844; called by muse, mutect2, varscan2
- PORCN | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs986541030, COSV58225807; called by muse, mutect2, varscan2
- WDR17 | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 91/199 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs188853445; called by muse, mutect2, varscan2
- MEX3D | c.1597G>A p.G533S | Missense Mutation (SNP) | VAF 191/442 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DHX15 | c.615T>G p.V205= | Silent (SNP) | VAF 44/363 reads (12%) | called by muse, mutect2, varscan2
- ISLR | c.30G>A p.A10= | Silent (SNP) | VAF 31/401 reads (8%) | catalogued as rs776190537; called by muse, mutect2
- TSPAN31 | c.576A>G p.L192= | Silent (SNP) | VAF 90/201 reads (45%) | called by muse, mutect2, varscan2
